Somatic mutation profile of tumor specimen MMRF_2271_1_BM_CD138pos (aliquot MMRF_2271_1_BM_CD138pos_T1_KHS5U_L09535) from MMRF case MMRF_2271, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 88.6 years (32,353 days).
Specimen MMRF_2271_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b06bd1b5-e970-49c3-bf32-9b3554d3face.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2271_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2271_1_PB_Whole_C3_KHS5U_L09536; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bb9ac59-9962-480e-b90a-7cfa038c155e

The open-access MAF lists 139 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 33, Intron 22, Silent 20, Splice Site 5, Frame Shift Del 4, Frame Shift Ins 3, Nonsense Mutation 3, RNA 3, 3'Flank 2, 5'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOB | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs755134927, COSV66398077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.1507A>G p.M503V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1475090100, COSV54337769; called by muse, mutect2, varscan2
- ERGIC1 | c.186C>G p.D62E | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.146); catalogued as rs1398374631; called by muse, mutect2
- HNRNPA2B1 | c.911G>A p.G304E (on ENST00000354667 / NM_031243.3; = p.G292E on NM_002137.4) | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61158212, COSV61160762; called by muse, mutect2, varscan2
- IGHV2-70 | c.219T>G p.D73E | Missense Mutation (SNP) | VAF 55/59 reads (93%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs181059057; called by muse, varscan2
- IGKV4-1 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 44/53 reads (83%) | catalogued as rs778196241; called by muse, mutect2, varscan2
- IPO5 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 108/127 reads (85%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99847662; called by muse, mutect2, varscan2
- ITSN1 | c.4640G>A p.R1547H | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs374602007; called by muse, mutect2, varscan2
- KHDRBS3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.71); catalogued as COSV100878428; called by muse, mutect2
- KMT2B | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1375377258, COSV52891722; called by muse, mutect2
- MED13 | c.3875C>A p.A1292D | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101181565, COSV67264922; called by muse, mutect2
- NOD2 | c.2212G>A p.G738R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1378981093; called by muse, mutect2, varscan2
- OR5D18 | c.800A>T p.N267I | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs748903028, COSV61739102; called by muse, mutect2
- PHF20L1 | c.83+1G>A p.X28_splice | Splice Site (SNP) | VAF 16/264 reads (6%) | catalogued as COSV55188762; called by muse, mutect2
- PLA2G4D | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs904193736; called by muse, mutect2
- RPS6KA6 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 68/81 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV53116024; called by muse, mutect2, varscan2
- SLC2A4RG | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761860991; called by muse, mutect2, varscan2
- SYNE1 | c.14923G>A p.G4975R (on ENST00000367255 / NM_182961.4; = p.G4904R on NM_033071.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV54981208; called by muse, mutect2
- TGFBI | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 59/131 reads (45%) | catalogued as COSV100526732; called by muse, mutect2, varscan2
- TRAF3 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as rs1566789877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWF | c.7408C>A p.Q2470K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as CM020777, COSV54616206; called by muse, mutect2, varscan2
- ZNF732 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.619); catalogued as rs1553837556, COSV69954847; called by muse, mutect2, varscan2
- ARHGEF17 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ASMTL | c.226-2A>T p.X76_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- CACNA1F | c.3025C>A p.L1009I | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDC42BPA | c.3226G>T p.D1076Y (on ENST00000334218 / NM_001366019.2; = p.D1063Y on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP54 | c.8558T>C p.F2853S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CHD7 | c.6101A>G p.D2034G | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL5A3 | c.2874+1G>T p.X958_splice | Splice Site (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- CPNE8 | c.1123A>C p.I375L | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, varscan2
- EHBP1 | c.2171_2172insTC p.Q724Hfs*4 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- FOXC2 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FSCB | c.1754C>A p.T585N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.268); called by muse, mutect2
- HEPHL1 | c.3463C>T p.P1155S | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); called by muse, mutect2
- IGHA1 | c.161_165del p.P54Qfs*121 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel, varscan2
- IGHA1 | c.26_30del p.F9Sfs*166 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | called by mutect2, pindel, varscan2
- INTS6 | c.2570+2T>G p.X857_splice | Splice Site (SNP) | VAF 9/12 reads (75%) | called by muse, varscan2
- MYO5C | c.1979+2T>A p.X660_splice | Splice Site (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
- NCOA6 | c.1793C>T p.T598I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OGFR | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPRK1 | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHGA3 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PGR | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PTGES2 | c.1061T>A p.M354K | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); called by muse, mutect2
- SIK2 | c.2008T>A p.S670T | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIPA1L2 | c.3608G>A p.G1203E | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC20A2 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC26A5 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SOCS6 | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- STAU1 | c.1561dup p.I521Nfs*23 (on ENST00000371856 / NM_001319135.1; = p.I440Nfs*23 on NM_004602.3) | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- TENT5C | c.451del p.R151Afs*4 | Frame Shift Del (DEL) | VAF 53/125 reads (42%) | called by mutect2, pindel, varscan2
- TNC | c.4892C>G p.A1631G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- TRAF3 | c.1489dup p.M497Nfs*54 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- TRAF3 | c.1645del p.I549Lfs*11 | Frame Shift Del (DEL) | VAF 6/86 reads (7%) | called by mutect2, pindel
- WASF2 | c.331T>A p.F111I | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ANKRD44 | c.2301C>T p.F767= | Silent (SNP) | VAF 51/130 reads (39%) | called by muse, mutect2, varscan2
- DES | c.87G>A p.P29= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV64660221; called by muse, mutect2, varscan2
- DUSP2 | c.328C>T p.L110= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs1022242643, COSV56619633; called by muse, mutect2, varscan2
- ELFN1 | c.1806C>T p.S602= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1010455764; called by mutect2, varscan2
- FAM98C | c.60T>A p.A20= | Silent (SNP) | VAF 44/119 reads (37%) | called by muse, mutect2
- IKBKE | c.402C>T p.R134= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs782809498, COSV65625649; called by muse, mutect2
- MCPH1 | c.1030T>C p.L344= | Silent (SNP) | VAF 101/176 reads (57%) | called by muse, mutect2, varscan2
- MLLT10 | c.537A>G p.E179= | Silent (SNP) | VAF 76/166 reads (46%) | called by muse, mutect2, varscan2
- MROH2B | c.3006T>C p.N1002= | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- NDUFB10 | c.501C>T p.A167= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as rs534213425; called by muse, mutect2, varscan2
- NPDC1 | c.27C>T p.S9= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1255984481; called by muse, mutect2, varscan2
- PAK3 | c.1386T>A p.S462= (on ENST00000262836 / NM_001324328.2; = p.S447= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2
- PCDHB16 | c.2121G>C p.L707= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV53360070; called by muse, mutect2
- PNPLA5 | c.96C>T p.R32= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1436201336; called by muse, mutect2, varscan2
- RNASE6 | c.402G>A p.K134= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as COSV58977627; called by muse, mutect2, varscan2
- SLC5A2 | c.111T>A p.I37= | Silent (SNP) | VAF 21/264 reads (8%) | called by muse, mutect2
- TMEM204 | c.453C>T p.I151= | Silent (SNP) | VAF 84/163 reads (52%) | catalogued as rs779508509, COSV54152411, COSV99559551; called by muse, mutect2, varscan2
- ZNF483 | c.1533T>C p.I511= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV58515782; called by muse, mutect2, varscan2
- ZNF620 | c.637C>A p.R213= | Silent (SNP) | VAF 66/168 reads (39%) | called by muse, mutect2, varscan2
- ZNF687 | c.3507C>T p.A1169= | Silent (SNP) | VAF 203/349 reads (58%) | catalogued as rs765727237; called by muse, mutect2, varscan2
- AC078899.1 | n.942A>T | RNA (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- ACTL6A | c.25+40G>A | Intron (SNP) | VAF 23/69 reads (33%) | catalogued as rs1326607440; called by muse, mutect2, varscan2
- ACTN2 | c.*816A>G | 3'UTR (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- ADRA1A | c.1270-7768dup | Intron (INS) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- ATP5MPL | c.149-334A>G | Intron (SNP) | VAF 2/8 reads (25%) | catalogued as rs1209171467; called by muse, mutect2
- BAG5 | c.*807del | 3'UTR (DEL) | VAF 4/34 reads (12%) | catalogued as COSV54572579; called by mutect2, varscan2
- BIRC3 | c.*1094C>G | 3'UTR (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- BTK | c.240+39T>C | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- C8orf74 | c.48+936A>T | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- CCDC30 | chr1:42654109 A>C | 3'Flank (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- CD48 | c.385+701T>C | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- CDH2 | c.*749C>A | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- CSMD1 | chr8:2935988 T>A | 3'Flank (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- CXorf65 | c.*98C>T | 3'UTR (SNP) | VAF 27/31 reads (87%) | called by muse, mutect2, varscan2
- CYTH2 | c.435-195C>T | Intron (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2
- DUSP22 | c.508+788G>A | Intron (SNP) | VAF 13/318 reads (4%) | catalogued as rs955495919; called by muse, mutect2
- EIF5 | c.*2802C>T | 3'UTR (SNP) | VAF 34/38 reads (89%) | called by muse, mutect2, varscan2
- ENPP1 | c.*414dup | 3'UTR (INS) | VAF 8/88 reads (9%) | called by mutect2, pindel
- EPHA7 | c.*2134T>A | 3'UTR (SNP) | VAF 54/121 reads (45%) | catalogued as rs576766958; called by muse, mutect2, varscan2
- FAM120A | c.*921_*936del | 3'UTR (DEL) | VAF 56/178 reads (31%) | called by pindel, varscan2
- FAM120A | c.*943A>C | 3'UTR (SNP) | VAF 62/184 reads (34%) | called by muse, varscan2
- FNIP1 | c.*2637C>A | 3'UTR (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- GPM6A | c.*1675A>T | 3'UTR (SNP) | VAF 42/117 reads (36%) | called by muse, mutect2, varscan2
- GRK2 | c.556-124C>T | Intron (SNP) | VAF 55/96 reads (57%) | called by muse, mutect2, varscan2
- GULP1 | c.844-1750T>G | Intron (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- HIPK1 | c.*1451A>G | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- KRR1 | c.*2450C>T | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- KRTAP10-9 | c.*223A>T | 3'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- LAMB1 | c.38-88C>A | Intron (SNP) | VAF 53/133 reads (40%) | called by muse, mutect2, varscan2
- METTL25 | c.*193_*195del | 3'UTR (DEL) | VAF 11/104 reads (11%) | catalogued as rs1248948461; called by pindel, varscan2
- MMRN2 | c.*1129A>T | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- NAMPTP1 | n.2137T>C | RNA (SNP) | VAF 36/351 reads (10%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.*1668G>A | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- NDUFB9 | c.-46T>G | 5'UTR (SNP) | VAF 20/186 reads (11%) | catalogued as rs749559905; called by muse, mutect2, varscan2
- NEDD4L | c.1065+48T>C | Intron (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- NHLH2 | c.-224A>G | 5'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- NPC1L1 | c.*585A>G | 3'UTR (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- PDE6H | c.*356C>T | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2
- PIGM | c.*503C>T | 3'UTR (SNP) | VAF 20/33 reads (61%) | catalogued as rs1257902137; called by muse, mutect2, varscan2
- PLOD2 | c.1501-1011G>A | Intron (SNP) | VAF 4/77 reads (5%) | called by muse, mutect2
- PPP2R2C | c.71-262C>T | Intron (SNP) | VAF 14/212 reads (7%) | catalogued as rs1327968264; called by muse, mutect2
- PRELP | c.*3463C>G | 3'UTR (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- RAB3IL1 | chr11:61920110 C>T | 5'Flank (SNP) | VAF 52/110 reads (47%) | catalogued as rs373760400; called by muse, mutect2, varscan2
- RNF144A | c.*539C>T | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- ROCK1P1 | n.1597G>A | RNA (SNP) | VAF 118/291 reads (41%) | called by muse, mutect2, varscan2
- RPS27A | c.48+137C>T | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as rs1024012782; called by muse, mutect2
- RUNDC1 | c.*85del | 3'UTR (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- SCAND1 | c.*8A>G | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- SCN3A | c.*634A>G | 3'UTR (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- SCUBE2 | c.256+35G>A | Intron (SNP) | VAF 28/238 reads (12%) | called by muse, mutect2, varscan2
- SHC4 | c.841-5771T>G | Intron (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- SIM1 | c.1168-17C>T | Intron (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- SPAG1 | c.1096+17A>G | Intron (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- STAG3 | c.2062-60G>A | Intron (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- TMSB4X | chrX:12975535 G>C | 5'Flank (SNP) | VAF 111/125 reads (89%) | called by muse, mutect2, varscan2
- TRAF1 | c.*957G>C | 3'UTR (SNP) | VAF 30/129 reads (23%) | called by muse, mutect2, varscan2
- TRMT9B | c.*2965A>C | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2, varscan2
- TTC9 | c.*3200C>A | 3'UTR (SNP) | VAF 40/50 reads (80%) | called by muse, mutect2, varscan2
- TXLNB | c.*950C>A | 3'UTR (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- ZIC3 | c.*405C>A | 3'UTR (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99798934; called by muse, mutect2, varscan2
- ZNF396 | c.418-18A>C | Intron (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- ZNF488 | c.*61C>T | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- ZNF680 | c.254-3915G>A | Intron (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- ZYG11B | c.*4708C>A | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
